Surgical pathology report (de-identified scan), TCGA case TCGA-Z4-A9VC, project TCGA-SARC (Sarcoma), tissue source site Cureline, specimen TCGA-Z4-A9VC-01A (Primary Tumor).

ICD-O-3
Liposarcoma, dedifferentiated 8858/3
Site @ Thigh NOS C49.2
QJ 11/27/14

Case #

Patient: **Age (years):** **Gender:** M

Clinical diagnosis: Soft tissue sarcoma of the left femoral region

Date of procurement: (mm/dd/yyyy)

Sample: histology #

Gross description: Skin patch with subcutaneous adipose tissue , skeletal muscle and tumor mass, size 20x15x8 cm

Nodular tumor mass size 15x12x6 cm. Mass reveals yellow lobulated stroma.

Distance from surgical resection lines:

Microscopic description: Mixoid liposarcoma from left femur. Histology consistent with mixoid liposarcoma G-6 FNCLCC (6/8), different degree of differentiation with predominance low grade component, with high mitotic activity (26 in10x400) and no necrotic nests, round cell component up to 80%, infiltrating adjacent adipose tissue and vessels.

Final diagnosis: Soft tissue dedifferentiated liposarcoma of the left femoral region

Confidential

Criteria	1/3/14	Yes	No

Source: NCI Genomic Data Commons file 21c83299-440a-4cdd-80b9-fdab10ed7ec1 (TCGA-Z4-A9VC.430E7694-EC8F-42D6-B673-D893948B86C0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).